Surgical pathology report (de-identified scan), TCGA case TCGA-43-5668, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-5668-01A (Primary Tumor).

[page 1 of 2]
██████████
██████████
██████████

SPECIMEN

- A. Right upper lobe
- B. Level 11
- C. Level 10
- D. Level 2
- E. Level 4R
- F. Level 7
- G. Level 9

CLINICAL NOTES

PRE-OP DIAGNOSIS: Pulmonary nodule.

FROZEN SECTION DIAGNOSIS

Lung, right upper lobe: Non-small cell carcinoma. ██████████

GROSS DESCRIPTION

A. Received unfixed for frozen section and tissue procurement, labeled "right upper lobe," is a 14 x 9 x 5 cm right upper lobectomy specimen. Several staple lines are present posteriorly. The pleura is intact, without puckering. There is a tumor, 2.6 x 2.6 x 2.4 cm, within the lung parenchyma and adjacent to a bronchus. It has an irregular border and a gray-white cut surface with incorporated anthracotic pigment. No other tumors are seen. A portion is submitted for frozen section diagnosis and tissue procurement. Additional representative sections submitted in six cassettes, including bronchial and vascular margins in A1-A2, tumor in A3 and hilar lymph nodes in A4-5. RS-6. ██████████

B. Received fresh and subsequently fixed in formalin labeled "level 11" are three red-black irregular soft tissue fragments, which range from 0.3 cm to 0.4 cm in greatest dimension. The specimens are entirely submitted in one cassette. AS-1.

C. Received in formalin labeled "level 10" is a 1.5 x 1 x 0.3 cm red-black irregular soft tissue fragment, which is entirely submitted in one cassette. AS-1.

D. Received in formalin labeled "level 2" is a 2.5 x 1.5 x 0.7 cm aggregate of pink-black irregular soft tissue fragments, which are entirely submitted in one cassette. AS-1.

E. Received fresh subsequently fixed in formalin labeled "4R" is a 1.2 x 1 x 0.3 cm black-red irregular soft tissue fragment, which is entirely submitted in one cassette. AS-1.

F. Received fresh subsequently fixed in formalin labeled "level 7" are two black-gray irregular soft tissue fragments, which are 1.5 and 1 cm in greatest dimension. Specimens are entirely submitted in one cassette. AS-1.

G. Received fresh subsequently fixed in formalin labeled

[page 2 of 2]
MICROSCOPIC DESCRIPTION

5, 4x5, 3, 14

DIAGNOSIS

- End Of Report ---

Source: NCI Genomic Data Commons file d56bba96-9be2-417e-b2e9-1b0259d85b93 (TCGA-43-5668.E41D4D1F-8334-42C6-8759-AD5366A11C93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).